Somatic mutation profile of tumor specimen C3N-02155-03 (aliquot CPT0118810006) from CPTAC case C3N-02155, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 45.4 years (16,568 days).
Specimen C3N-02155-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 422feba3-4c12-43eb-8ca7-243048278391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02155-31 (Blood Derived Normal), aliquot CPT0120050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fd2271e-4d08-44d6-96a2-d76079af8c38

The open-access MAF lists 201 somatic variants for this specimen: 140 protein-altering or splice-affecting, 37 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 37, Intron 13, Frame Shift Del 6, Nonsense Mutation 5, 5'UTR 5, 3'UTR 4, Splice Site 2, 3'Flank 1, Splice Region 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 612/1196 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12575T>C p.L4192P | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1157826587; called by muse, mutect2
- ASB14 | c.644C>T p.T215M (on ENST00000389601; = p.T214M on NM_001142733.3) | Missense Mutation (SNP) | VAF 98/547 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1018152149; called by muse, mutect2, varscan2
- ATMIN | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs761476797; called by muse, mutect2, varscan2
- BEND2 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 118/197 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.895); catalogued as rs747951664, COSV101191720; called by muse, varscan2
- BRCA2 | c.6818G>A p.R2273K | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs587782174, COSV66453780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC80 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 61/451 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52816341; called by muse, mutect2, varscan2
- CFAP43 | c.4772G>A p.C1591Y | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs747486258; called by muse, mutect2, varscan2
- DBF4B | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs367600377; called by muse, mutect2, varscan2
- DLL1 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 86/639 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs1243424926; called by muse, mutect2, varscan2
- DNAH10 | c.11527G>A p.E3843K (on ENST00000409039; = p.E3782K on NM_207437.3) | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV68999230; called by muse, mutect2, varscan2
- DNAH7 | c.11182G>C p.D3728H | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV56765423; called by muse, mutect2, varscan2
- FCHSD2 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 93/628 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60806685; called by muse, mutect2, varscan2
- FLT4 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs757667364, COSV56107763; called by muse, mutect2, varscan2
- FREM3 | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1268480051; called by muse, mutect2, varscan2
- FUT9 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765166497, COSV100134026; called by muse, mutect2, varscan2
- GPR141 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs141399721, COSV57734238; called by muse, mutect2
- HDAC9 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 85/509 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67785982; called by muse, mutect2, varscan2
- HNRNPDL | c.178del p.H60Tfs*16 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | catalogued as rs764970578, COSV55023147; called by mutect2, pindel, varscan2
- HPD | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 98/714 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.305); catalogued as rs1043916023; called by muse, mutect2, varscan2
- HPD | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 146/742 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56644029; called by muse, mutect2, varscan2
- ITGAD | c.2292C>G p.F764L | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1374291141, COSV66759124; called by muse, mutect2, varscan2
- LAMA5 | c.6742C>T p.R2248W | Missense Mutation (SNP) | VAF 44/369 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs769500367, COSV53356656; called by muse, mutect2, varscan2
- MARCHF1 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); catalogued as COSV56812724; called by muse, mutect2, varscan2
- NFATC2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771040521, COSV101043875; called by muse, mutect2, varscan2
- NFE2 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.16); catalogued as rs1323022400; called by muse, mutect2, varscan2
- NOMO1 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs763139022; called by muse, mutect2, varscan2
- NPSR1 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62204077; called by muse, mutect2
- OSGEP | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 46/680 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV52831919; called by muse, mutect2
- PCDHA9 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 97/620 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV65331092; called by muse, mutect2, varscan2
- PDLIM2 | c.453C>G p.I151M (on ENST00000397760; = p.I401M on NM_021630.6) | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56134008, COSV56135416; called by muse, mutect2, varscan2
- PFAS | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560782236; called by muse, mutect2, varscan2
- PLPP7 | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64841453; called by muse, mutect2
- POM121L12 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 45/618 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as COSV68692529; called by muse, mutect2
- PPP4R3B | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.206); catalogued as rs1463216082; called by muse, mutect2, varscan2
- PTCD3 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1161613580; called by muse, mutect2, varscan2
- RAD51C | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs1411093088; called by muse, mutect2, varscan2
- RPS6KB1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56680143; called by muse, mutect2, varscan2
- RSKR | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.1); catalogued as COSV56380685; called by muse, mutect2
- RYR3 | c.4738del p.L1580Cfs*44 | Frame Shift Del (DEL) | VAF 43/330 reads (13%) | catalogued as COSV101212844; called by mutect2, pindel, varscan2
- SDK1 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 54/629 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); catalogued as COSV67376382; called by muse, mutect2
- SH3PXD2A | c.2548G>A p.A850T (on ENST00000369774 / NM_001365079.1; = p.A822T on NM_014631.2) | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.5); catalogued as rs764554398, COSV60120511; called by muse, mutect2, varscan2
- SLC4A1 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 122/818 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1222836115, COSV52263439; called by mutect2, varscan2
- SLIT3 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372219038, COSV100270232; called by muse, mutect2, varscan2
- SRGAP3 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 84/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1033693138, COSV64532959; called by muse, mutect2, varscan2
- TBC1D1 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 61/506 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV54717168; called by muse, mutect2, varscan2
- TIAM1 | c.3251T>G p.L1084R | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54558835; called by muse, mutect2, varscan2
- TMEM11 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as rs1213473338; called by muse, mutect2, varscan2
- TRPC7 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs748677264, COSV61457508; called by muse, mutect2, varscan2
- WASF1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs141943257; called by muse, mutect2, varscan2
- ZNF292 | c.6145A>T p.S2049C | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV60535121; called by muse, mutect2, varscan2
- ACTC1 | c.1134A>T p.*378Yext*46 | Nonstop Mutation (SNP) | VAF 95/533 reads (18%) | called by muse, mutect2, varscan2
- ADCY3 | c.2661G>C p.W887C | Missense Mutation (SNP) | VAF 99/385 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKFN1 | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ANKRD54 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATF7IP2 | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 64/421 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATG2B | c.3385C>G p.P1129A | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP6V1C2 | c.416C>G p.T139R | Missense Mutation (SNP) | VAF 98/448 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BRSK1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- BUB3 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C11orf54 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf99 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 122/1112 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- C1QTNF1 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 53/508 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf201 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 24/183 reads (13%) | called by muse, varscan2
- CAMSAP2 | c.2947G>A p.V983I (on ENST00000236925 / NM_001297707.2; = p.V972I on NM_203459.3) | Missense Mutation (SNP) | VAF 74/588 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- CAPN10 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CCAR1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- CCDC168 | c.13005G>T p.M4335I | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CDH20 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CNKSR3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL12A1 | c.525G>C p.E175D | Missense Mutation (SNP) | VAF 172/746 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBNL | c.967C>A p.P323T (on ENST00000448521 / NM_001014436.3; = p.P324T on NM_014063.7) | Missense Mutation (SNP) | VAF 69/447 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DDX5 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 49/523 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2
- DHX29 | c.896A>C p.K299T | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DMXL2 | c.4943G>T p.C1648F | Missense Mutation (SNP) | VAF 63/418 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DNAH17 | c.12763G>A p.G4255R | Missense Mutation (SNP) | VAF 62/539 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPY19L1 | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DSP | c.8218G>T p.E2740* | Nonsense Mutation (SNP) | VAF 60/457 reads (13%) | called by muse, mutect2, varscan2
- DYSF | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 63/499 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- EEFSEC | c.852C>G p.D284E | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHMT2 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM151A | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 43/303 reads (14%) | called by muse, mutect2, varscan2
- FAM217B | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.067); called by muse, mutect2
- FBN2 | c.5996G>A p.C1999Y | Missense Mutation (SNP) | VAF 149/497 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FBXL4 | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 98/926 reads (11%) | called by muse, mutect2, varscan2
- GAGE2E | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 58/907 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.068); called by muse, varscan2
- GPT2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- H3-2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 190/877 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HDAC9 | c.3121G>T p.A1041S (on ENST00000441542 / NM_178425.3; = p.A1038S on NM_178423.3) | Missense Mutation (SNP) | VAF 46/529 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- IKZF5 | c.861G>T p.M287I | Missense Mutation (SNP) | VAF 113/574 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IQGAP3 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 38/429 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- ITPKB | c.1932+2T>C p.X644_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- KCNRG | c.812del p.K271Rfs*27 | Frame Shift Del (DEL) | VAF 32/174 reads (18%) | called by mutect2, pindel
- KHDRBS2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 45/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF13B | c.3430del p.V1144* | Frame Shift Del (DEL) | VAF 50/408 reads (12%) | called by mutect2, pindel, varscan2
- KLHL24 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2C | c.13956G>C p.Q4652H | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LRRC7 | c.1993G>C p.E665Q (on ENST00000651989 / NM_001370785.2; = p.E632Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MED12L | c.2390A>T p.D797V | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED13L | c.1685A>C p.Q562P | Missense Mutation (SNP) | VAF 60/377 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- MRPL48 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYOM2 | c.1586del p.L529Pfs*37 | Frame Shift Del (DEL) | VAF 54/299 reads (18%) | called by mutect2, pindel, varscan2
- NETO1 | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 109/421 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOP56 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, varscan2
- OLFM4 | c.665A>T p.K222M | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OR14J1 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 70/643 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- OR52J3 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- P4HA1 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PCNT | c.8491G>A p.E2831K | Missense Mutation (SNP) | VAF 99/760 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PDK3 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PHC3 | c.2008C>G p.P670A (on ENST00000494943 / NM_001308116.2; = p.P682A on NM_024947.4) | Missense Mutation (SNP) | VAF 78/472 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PHF2 | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLA2G4C | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLG | c.1564C>G p.P522A | Missense Mutation (SNP) | VAF 93/668 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PPID | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 100/532 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PPM1L | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R37 | c.1861C>A p.Q621K | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, varscan2
- PRTG | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/230 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PTCHD1 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 109/170 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RASGRP4 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SHC3 | c.963-1G>C p.X321_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- SNAP25 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPG7 | c.1803G>T p.Q601H (on ENST00000268704; = p.Q608H on NM_003119.4) | Missense Mutation (SNP) | VAF 91/550 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ST3GAL5 | c.730-6C>T | Splice Region (SNP) | VAF 194/802 reads (24%) | called by muse, mutect2, varscan2
- SZT2 | c.4063C>T p.H1355Y (on ENST00000634258 / NM_001365999.1; = p.H1298Y on NM_015284.4) | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TLK1 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TLL1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 63/437 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- TMEM131L | c.2461G>C p.D821H | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC18 | c.8054C>T p.A2685V | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TOGARAM1 | c.5098C>T p.Q1700* | Nonsense Mutation (SNP) | VAF 137/636 reads (22%) | called by muse, mutect2, varscan2
- TRBV4-1 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); called by muse, varscan2
- TRIM33 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TSPAN10 | c.197C>T p.S66L (on ENST00000574882 / NM_001290212.1; = p.S28L on NM_031945.4) | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP42 | c.2329C>G p.P777A | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.124); called by muse, mutect2
- VPS41 | c.1780del p.Q594Sfs*60 | Frame Shift Del (DEL) | VAF 67/624 reads (11%) | called by mutect2, pindel, varscan2
- WASHC2C | c.2676G>T p.K892N | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY3 | c.10235_10237dup p.E3412dup | In Frame Ins (INS) | VAF 40/260 reads (15%) | called by mutect2, pindel, varscan2
- WRN | c.2227dup p.T743Nfs*22 | Frame Shift Ins (INS) | VAF 70/447 reads (16%) | called by pindel, varscan2
- ZNF292 | c.1511A>C p.N504T | Missense Mutation (SNP) | VAF 100/770 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.014); called by mutect2, varscan2
- ZNF766 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ARL11 | c.12G>A p.V4= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99949183; called by muse, mutect2, varscan2
- ATAD3C | c.762C>T p.L254= | Silent (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- ATP10A | c.138G>A p.K46= | Silent (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- C16orf71 | c.193C>T p.L65= | Silent (SNP) | VAF 97/311 reads (31%) | catalogued as rs1415881934, COSV99070130; called by muse, mutect2, varscan2
- CACNA1S | c.1980C>T p.A660= | Silent (SNP) | VAF 202/996 reads (20%) | catalogued as rs1019612686; called by muse, mutect2, varscan2
- FANCL | c.22C>T p.L8= | Silent (SNP) | VAF 131/1071 reads (12%) | catalogued as rs764378405; called by muse, mutect2, varscan2
- FURIN | c.1854C>T p.F618= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as rs767680799, COSV51575858; called by muse, mutect2, varscan2
- GUCY1B1 | c.15G>C p.V5= | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- GZMH | c.129G>A p.E43= | Silent (SNP) | VAF 48/962 reads (5%) | called by muse, mutect2
- HEG1 | c.2539C>T p.L847= | Silent (SNP) | VAF 93/777 reads (12%) | catalogued as COSV60762276; called by muse, mutect2, varscan2
- HNRNPCL1 | c.525G>A p.L175= | Silent (SNP) | VAF 145/1092 reads (13%) | catalogued as COSV58613280; called by muse, mutect2, varscan2
- KCTD12 | c.264C>T p.L88= | Silent (SNP) | VAF 65/322 reads (20%) | catalogued as rs1381821580; called by muse, mutect2, varscan2
- KLHL12 | c.1143C>A p.I381= | Silent (SNP) | VAF 51/349 reads (15%) | called by muse, mutect2, varscan2
- KRT80 | c.291A>T p.L97= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV57548349; called by muse, mutect2
- LARGE2 | c.81C>T p.F27= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- LRP1 | c.5061C>T p.A1687= | Silent (SNP) | VAF 31/271 reads (11%) | catalogued as COSV99673952; called by muse, mutect2, varscan2
- LYPD2 | c.375G>C p.L125= | Silent (SNP) | VAF 66/319 reads (21%) | catalogued as rs964462832; called by muse, mutect2, varscan2
- MAP6 | c.1689T>A p.G563= | Silent (SNP) | VAF 54/406 reads (13%) | called by muse, mutect2, varscan2
- MTMR10 | c.1887G>A p.Q629= | Silent (SNP) | VAF 101/525 reads (19%) | called by muse, mutect2, varscan2
- MYH15 | c.3276G>A p.L1092= | Silent (SNP) | VAF 32/177 reads (18%) | called by muse, varscan2
- NOP56 | c.360G>A p.E120= | Silent (SNP) | VAF 50/357 reads (14%) | called by muse, mutect2, varscan2
- NOP56 | c.903G>A p.G301= | Silent (SNP) | VAF 50/400 reads (13%) | catalogued as rs750766614; called by muse, mutect2, varscan2
- NWD1 | c.2031G>A p.R677= | Silent (SNP) | VAF 87/229 reads (38%) | called by muse, mutect2, varscan2
- NWD1 | c.3483G>A p.G1161= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV60342893; called by muse, varscan2
- OR1S2 | c.237A>T p.L79= | Silent (SNP) | VAF 83/533 reads (16%) | called by muse, mutect2, varscan2
- OR52E6 | c.915G>A p.L305= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs540768482, COSV61431620; called by muse, varscan2
- PAPPA2 | c.4185C>T p.S1395= | Silent (SNP) | VAF 32/362 reads (9%) | catalogued as rs774121481; called by muse, mutect2
- PFN3 | c.300G>C p.V100= | Silent (SNP) | VAF 55/376 reads (15%) | called by muse, mutect2, varscan2
- PKP2 | c.2253G>A p.S751= | Silent (SNP) | VAF 77/473 reads (16%) | catalogued as rs139098675; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBCK1 | c.1101C>T p.F367= (on ENST00000356286 / NM_031229.4; = p.F325= on NM_006462.6) | Silent (SNP) | VAF 49/485 reads (10%) | catalogued as rs762666056; called by muse, mutect2, varscan2
- RP1L1 | c.1437G>T p.G479= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs1312611287, COSV66759160; called by muse, mutect2, varscan2
- SLX4IP | c.891G>A p.R297= | Silent (SNP) | VAF 44/274 reads (16%) | catalogued as COSV57947225; called by muse, mutect2, varscan2
- TNXB | c.3444C>T p.G1148= | Silent (SNP) | VAF 81/507 reads (16%) | called by muse, mutect2, varscan2
- TOM1 | c.1167C>G p.P389= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as rs924685343; called by muse, mutect2, varscan2
- TPO | c.1170C>T p.F390= | Silent (SNP) | VAF 45/315 reads (14%) | catalogued as COSV61102487; called by muse, mutect2, varscan2
- TSPAN19 | c.492G>A p.K164= | Silent (SNP) | VAF 53/279 reads (19%) | catalogued as COSV70813450; called by muse, mutect2, varscan2
- ZBTB24 | c.780A>G p.R260= | Silent (SNP) | VAF 124/736 reads (17%) | catalogued as rs772140449; called by muse, mutect2, varscan2
- ADAM20P1 | n.1644A>G | RNA (SNP) | VAF 104/559 reads (19%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>C | 5'UTR (SNP) | VAF 41/242 reads (17%) | catalogued as COSV58113041; called by muse, mutect2, varscan2
- ARHGEF1 | c.1121+169C>T | Intron (SNP) | VAF 74/410 reads (18%) | catalogued as rs1350765885; called by muse, mutect2, varscan2
- C17orf80 | c.1730-2021G>C | Intron (SNP) | VAF 48/330 reads (15%) | called by muse, mutect2, varscan2
- C20orf204 | c.*95C>A | 3'UTR (SNP) | VAF 50/408 reads (12%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3753C>T | Intron (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- CCAR2 | c.-127C>T | 5'UTR (SNP) | VAF 56/310 reads (18%) | called by muse, mutect2, varscan2
- ETFA | c.883-1935A>G | Intron (SNP) | VAF 68/508 reads (13%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1134del | 3'UTR (DEL) | VAF 67/441 reads (15%) | called by mutect2, varscan2
- HAL | c.-19C>A | 5'UTR (SNP) | VAF 87/280 reads (31%) | called by muse, mutect2, varscan2
- ITPRID2 | c.*54C>A | 3'UTR (SNP) | VAF 40/246 reads (16%) | called by muse, mutect2, varscan2
- KHK | c.210-224G>C | Intron (SNP) | VAF 108/787 reads (14%) | catalogued as COSV99566147; called by muse, mutect2, varscan2
- MT1G | c.97+79G>A | Intron (SNP) | VAF 62/378 reads (16%) | called by muse, mutect2, varscan2
- NDUFV1 | c.73-46C>G | Intron (SNP) | VAF 78/407 reads (19%) | called by muse, mutect2, varscan2
- NOP56 | c.1282-75G>A | Intron (SNP) | VAF 78/620 reads (13%) | catalogued as COSV61389978; called by muse, varscan2
- NRG2 | c.701-16838G>A | Intron (SNP) | VAF 22/187 reads (12%) | catalogued as rs777682955; called by muse, mutect2, varscan2
- REPIN1 | c.-308C>G | 5'UTR (SNP) | VAF 32/304 reads (11%) | called by muse, varscan2
- SEMA6C | c.*149G>C | 3'UTR (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- SFPQ | chr1:35178042 G>T | 3'Flank (SNP) | VAF 23/202 reads (11%) | catalogued as rs1311701666; called by muse, mutect2, varscan2
- SMG7 | c.30-10559G>A | Intron (SNP) | VAF 33/206 reads (16%) | catalogued as rs898054613; called by muse, mutect2, varscan2
- SYPL2 | c.-52C>T | 5'UTR (SNP) | VAF 26/201 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10360+4211C>T | Intron (SNP) | VAF 65/401 reads (16%) | catalogued as rs990157560, COSV59862241; called by muse, mutect2, varscan2
- ZNF451 | c.186+2730T>C | Intron (SNP) | VAF 76/474 reads (16%) | called by muse, varscan2
- ZNF451 | c.186+2731G>T | Intron (SNP) | VAF 81/471 reads (17%) | called by muse, mutect2, varscan2
